Somatic mutation profile of tumor specimen TCGA-MR-A8JO-01A (aliquot TCGA-MR-A8JO-01A-12D-A35Z-10) from TCGA case TCGA-MR-A8JO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 34.7 years (12,669 days).
Specimen TCGA-MR-A8JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bb40aea-3e1b-4543-8e24-6cb112da606c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MR-A8JO-10A (Blood Derived Normal), aliquot TCGA-MR-A8JO-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bbe3e4c-a48e-4e7f-9392-bad1bb07f6e9

The open-access MAF lists 30 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Silent 4, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFY1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100492129; called by muse, mutect2
- ATP1A1 | c.2033T>C p.L678P | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99814034; called by muse, mutect2, varscan2
- BCHE | c.1523del p.P508Qfs*22 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as COSV52254080; called by mutect2, pindel
- CCND2 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99713914, COSV99714229; called by muse, mutect2, varscan2
- CHRNA4 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100937304; called by muse, mutect2
- COL5A1 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs377125301; called by muse, mutect2, varscan2
- DPP6 | c.1924G>A p.E642K (on ENST00000377770 / NM_001364500.2; = p.E580K on NM_001936.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.052); catalogued as rs769755446, COSV100122400, COSV59601313; called by muse, mutect2, varscan2
- DPP6 | c.2153G>A p.S718N (on ENST00000377770 / NM_001364500.2; = p.S656N on NM_001936.5) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100122401; called by muse, mutect2, varscan2
- E2F8 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363350887, COSV100001209; called by muse, mutect2, varscan2
- FRMD4A | c.2729G>A p.G910D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV100660974; called by muse, mutect2
- GABBR1 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100589357; called by muse, mutect2
- MED13 | c.3588C>A p.C1196* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as COSV101180690; called by muse, mutect2, varscan2
- MED13 | c.3587G>A p.C1196Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101180691; called by muse, mutect2, varscan2
- N4BP2 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as COSV99788057; called by muse, mutect2, varscan2
- OR5M8 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100510497; called by muse, mutect2
- OSBP | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370601390, COSV55666706; called by muse, mutect2, varscan2
- PPM1D | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as rs1315208220, COSV100010508, COSV59958163; called by muse, mutect2, varscan2
- RNF220 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100131694; called by muse, mutect2, varscan2
- SPINK5 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV99805906; called by muse, mutect2, varscan2
- STAB1 | c.4340C>A p.S1447Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100400929; called by muse, mutect2, varscan2
- TBX19 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100892302; called by muse, mutect2, varscan2
- THBS1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs760002107, COSV52953751; called by muse, mutect2, varscan2
- ZFP28 | c.1805T>C p.I602T | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as COSV100019150; called by muse, mutect2, varscan2
- ZRANB3 | c.883A>T p.I295L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99922299; called by muse, mutect2, varscan2
- BAHD1 | c.2285dup p.L763Pfs*7 | Frame Shift Ins (INS) | VAF 30/139 reads (22%) | called by mutect2, pindel, varscan2
- PRDM5 | c.1746del p.F582Lfs*3 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- CEP41 | c.81A>G p.K27= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99782481; called by muse, mutect2, varscan2
- PCSK9 | c.897C>T p.A299= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV56162872; called by muse, mutect2
- SMTNL1 | c.120G>A p.K40= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV101216174; called by muse, mutect2, varscan2
- STARD13 | c.651A>G p.T217= (on ENST00000336934 / NM_001243476.3; = p.T99= on NM_052851.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99715315; called by muse, mutect2, varscan2
